Gene-level copy-number profile of tumor specimen TCGA-OR-A5KS-01A from TCGA case TCGA-OR-A5KS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 72.3 years (26,404 days).
Specimen TCGA-OR-A5KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.fcb181fe-de38-4d26-846a-00c718238ecd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8086a4f9-b092-4e93-a9ca-20c432f46512

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 323; copy number 2: 5,595; copy number 3: 27,785; copy number 4: 10,496; copy number 5: 5,595; copy number 6: 9,523; copy number 7: 401; copy number 8: 4; copy number 9: 67; copy number 10: 2; copy number 11: 11; copy number 12: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KS-01A-11D-A309-01): tumor purity 0.87, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,614,773–245,676,478, 2 genes: AC104462.2, AC104462.1.
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 471 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:200,586,014–200,827,338, 8 genes, copy number 7 (within-gene range 3–7): AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1.
- chr5:9,621,377–9,903,852, 6 genes, copy number 9 (within-gene range 6–9): AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:15,500,180–15,939,795, 2 genes, copy number 10 (within-gene range 6–10): FBXL7, CTD-2350J17.1.
- chr5:66,298,394–69,043,821, 37 genes, copy number 7 (within-gene range 6–7): AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2, AC010280.1, AC010280.3, AC093523.1, VWA8P1, U8, AC093248.1, RN7SKP251, LINC02198, AC010273.3.
- chr5:71,587,288–74,536,976, 55 genes, copy number 7 (within-gene range 5–7): MCCC2, CARTPT, AC143336.1, AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22, H2BL1P, Y_RNA, AC035140.1, TNPO1, MIR4804, RPL35AP13, AC008972.1, AC008972.2, FCHO2, AC020893.1, CHP1P1, TMEM171, AC116345.3, AC116345.2, TMEM174, AC116345.4, AC116345.1, LINC02230, AC099522.1, FOXD1, FOXD1-AS1, LINC01385, LINC01386, AC099522.2, BTF3, FUNDC2P1, ANKRA2, UTP15, ARHGEF28, AC091868.2, AC091868.1, RNU7-196P, AC093283.1, LINC02122, LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr5:132,003,592–137,889,394, 163 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:172,609,094–172,785,424, 11 genes, copy number 11: AC027309.3, NEURL1B, AC027309.2, MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4.
- chr5:173,607,145–173,961,980, 7 genes, copy number 7–12: BOD1, LINC01863, LINC01942, LINC01484, AC008674.1, LINC01485, CPEB4.
- chr6:53,267,398–53,355,065, 5 genes, copy number 7–8: ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28.
- chr8:1,755,778–1,801,711, 1 gene, copy number 9 (within-gene range 6–9): CLN8.
- chr8:1,763,888–2,165,552, 13 genes, copy number 9 (within-gene range 6–9): AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160.
- chr8:101,034,868–102,154,725, 29 genes, copy number 7 (within-gene range 6–7): FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1.
- chr9:18,858,906–19,049,358, 1 gene, copy number 8 (within-gene range 4–8): SAXO1.
- chr12:46,183,063–48,529,897, 86 genes, copy number 7 (broad region; genes not listed).
- chr12:124,622,290–124,935,895, 10 genes, copy number 9: AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19.
- chr16:2,332,313–2,709,030, 37 genes, copy number 9 (within-gene range 5–9): AC106820.1, ABCA17P, CCNF, AC106820.6, MIR6767, AC106820.3, AC106820.5, TEDC2, MIR6768, AC106820.2, NTN3, TBC1D24, AC106820.4, AC093525.2, ATP6V0C, AC093525.1, AC093525.8, AMDHD2, CEMP1, MIR3178, PDPK1, AC093525.6, AC093525.5, AC093525.7, AC093525.4, AC093525.3, AC093525.9, AC093525.10, AC141586.5, AC141586.3, AC141586.1, PDPK2P, AC141586.4, AC141586.2, ERVK13-1, KCTD5, AC092117.2.

Autosomal genes at a single copy (total copy number 1): 323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
